Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A77X, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A77X-01A (Primary Tumor).

ICD-O-3
Oligoastrocytoma, grade II
9382/3
Date ^{CSCF} Brain, supratentorial NOS
C71.0
path
Brain, frontal lobe
C71.1
W 8/20/13

Case #

Patient: **Age (years):** **Gender:** Female

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by dense white pieces from right frontal lobe

Microscopic description:

Received material is consistent with oligoastrocytoma, with mitosis, Grade II.

Final diagnosis: Oligoastrocytoma: Grade II

Confidential

Criteria	W 8/13/13	Yes	No

Source: NCI Genomic Data Commons file b2c3f362-3a3a-4299-bbc2-71731a24f842 (TCGA-P5-A77X.E1A92E19-6BC7-4AA0-AC3D-590305FC4FF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).